Gene-level copy-number profile of tumor specimen C3N-00829-01 (profiled together with C3N-00829-02) from CPTAC case C3N-00829, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.1 years (19,384 days).
Specimen C3N-00829-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2398c61-6645-4ba0-a64c-f98a2dc2157c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00829-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,263 have no estimate.
https://portal.gdc.cancer.gov/files/d38d80e1-0ad1-4a3f-b05c-82368185404b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 318; copy number 2: 24,933; copy number 3: 24,593; copy number 4: 5,169; copy number 5: 2,488; copy number 6: 465; copy number 7: 282; copy number 8: 14; copy number 9: 4; copy number 11: 33; copy number 14: 40; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:39,734,670–39,810,097, 4 genes: RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–2): BX664615.2.
- chr9:41,979,352–42,011,610, 2 genes: CR788268.1, RN7SL343P.
- chr10:74,120,255–74,150,842, 1 gene (within-gene range 0–2): AP3M1.
- chr10:74,344,550–74,344,805, 1 gene (within-gene range 0–2): TIMM9P1.
- chr16:32,008,438–32,084,785, 5 genes (within-gene range 0–1): AC142381.4, IGHV1OR16-1, AC142381.1, IGHV1OR16-3, IGHV3OR16-9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 370 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,275,951–63,779,336, 12 genes, copy number 8 (within-gene range 4–8): LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr8:35,235,475–37,849,861, 40 genes, copy number 14: UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2.
- chr8:116,642,130–138,914,041, 280 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr9:40,346,144–40,358,682, 3 genes, copy number 9: CNN2P2, GXYLT1P3, AL591471.1.
- chr18:21,871,446–23,586,506, 35 genes, copy number 11–19: AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 306. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
